Somatic mutation profile of tumor specimen TCGA-AJ-A5DV-01A (aliquot TCGA-AJ-A5DV-01A-11D-A27P-09) from TCGA case TCGA-AJ-A5DV, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G3; Age at diagnosis: 65.4 years (23,892 days).
Specimen TCGA-AJ-A5DV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 45593b2c-1bbe-4a32-839c-278c211d20ab.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AJ-A5DV-10A (Blood Derived Normal), aliquot TCGA-AJ-A5DV-10A-01D-A27P-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/18b8d60e-2175-4278-b63c-24c0f5610a50

The open-access MAF lists 90 somatic variants for this specimen: 75 protein-altering or splice-affecting, 14 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 59, Silent 14, Nonsense Mutation 5, Frame Shift Del 5, Frame Shift Ins 3, In Frame Del 3, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BCOR | c.4376A>G p.N1459S (on ENST00000378444 / NM_001123385.2; = p.N1425S on NM_017745.6) | Missense Mutation (SNP) | VAF 38/106 reads (36%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.578); catalogued as rs199538037, COSV60698733; called by muse, mutect2, varscan2
- CTNNB1 | c.100G>A p.G34R | Missense Mutation (SNP) | VAF 24/77 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913399, COSV62687911, COSV62687931, COSV62721471; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- NFE2L2 | c.100C>G p.R34G | Missense Mutation (SNP) | VAF 31/86 reads (36%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67960061, COSV67960966; called by muse, mutect2, varscan2
- PIK3R1 | c.1727_1729del p.T576del (on ENST00000521381 / NM_181523.3; = p.T306del on NM_181504.4) | In Frame Del (DEL) | VAF 17/71 reads (24%) | hotspot (GDC flag); catalogued as rs1057519842; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- PTEN | c.697C>T p.R233* | Nonsense Mutation (SNP) | VAF 39/107 reads (36%) | hotspot (GDC flag); catalogued as rs121909219, CM971277, COSV64288653, COSV64291717, COSV64302607, COSV64306399, COSV64306519, COSV64311585, COSV99058021; ClinVar: pathogenic / not provided; called by muse, mutect2, varscan2
- AEBP1 | c.2869G>A p.A957T | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1473933290, COSV56261112; called by muse, mutect2, varscan2
- ANAPC1 | c.2413C>A p.H805N | Missense Mutation (SNP) | VAF 56/153 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.018); catalogued as COSV100594687; called by muse, mutect2, varscan2
- ARID1A | c.3049G>T p.E1017* | Nonsense Mutation (SNP) | VAF 28/87 reads (32%) | catalogued as COSV100251522, COSV61376694; called by muse, mutect2, varscan2
- ATP2B2 | c.503C>T p.T168M | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749396633, COSV59488346, COSV59493792, COSV59510669; called by muse, mutect2, varscan2
- ATRNL1 | c.2264T>A p.I755N | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.44); catalogued as COSV100745268; called by muse, mutect2, varscan2
- BBS12 | c.2024G>C p.R675P | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100044923; called by muse, mutect2
- C6orf118 | c.268C>T p.R90C | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.747); catalogued as rs374675192; called by muse, mutect2, varscan2
- CD1C | c.250C>A p.L84I | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.084); catalogued as COSV100939386; called by muse, mutect2, varscan2
- CHERP | c.1426C>A p.R476S | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.24); catalogued as rs1172089598, COSV99550226; called by muse, mutect2, varscan2
- CHTF18 | c.2266G>A p.A756T | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as COSV99242775; called by muse, mutect2, varscan2
- DENND5A | c.1159A>G p.I387V | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.029); catalogued as rs768313474, COSV100064584; called by muse, varscan2
- DIPK2B | c.895G>A p.V299I | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT tolerated (0.8); PolyPhen benign (0.003); catalogued as rs778769796, COSV101211666; called by muse, mutect2, varscan2
- ERAL1 | c.976C>T p.Q326* | Nonsense Mutation (SNP) | VAF 27/59 reads (46%) | catalogued as COSV99650325; called by muse, mutect2, varscan2
- F5 | c.5177G>A p.R1726Q | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs369516642; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- FBN1 | c.6048G>T p.E2016D | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV100354875; called by muse, mutect2, varscan2
- FILIP1 | c.3559C>G p.R1187G | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.605); catalogued as rs766890609, COSV52727336; called by muse, mutect2, varscan2
- GALR2 | c.815C>T p.A272V | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.71); PolyPhen benign (0.228); catalogued as COSV57165629; called by muse, mutect2, varscan2
- GDF6 | c.1214C>T p.T405M | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54625724; called by muse, mutect2, varscan2
- H3C8 | c.365C>T p.P122L | Missense Mutation (SNP) | VAF 32/87 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.422); catalogued as rs1455019791, COSV100010095, COSV100010123; called by muse, mutect2, varscan2
- HNRNPH1 | c.617G>T p.R206L | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.014); catalogued as COSV100270589, COSV61487590, COSV61487822; called by muse, mutect2, varscan2
- HSPG2 | c.9851C>T p.A3284V | Missense Mutation (SNP) | VAF 31/104 reads (30%) | SIFT tolerated (0.68); PolyPhen benign (0.125); catalogued as rs779942755, COSV101013452; called by muse, mutect2, varscan2
- KCNJ3 | c.599C>T p.A200V | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV54534252; called by muse, mutect2, varscan2
- KIAA1109 | c.3187C>G p.R1063G | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.982); catalogued as COSV52689591, COSV99161323; called by muse, mutect2, varscan2
- KLHL42 | c.1148A>G p.K383R | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.991); catalogued as rs1426784706, COSV101179749; called by muse, mutect2, varscan2
- KRT82 | c.241C>T p.R81* | Nonsense Mutation (SNP) | VAF 15/68 reads (22%) | catalogued as rs76579608, COSV57787248; called by muse, mutect2, varscan2
- LRIT1 | c.898C>T p.H300Y | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV100928076; called by muse, mutect2, varscan2
- MAP3K5 | c.2737G>T p.A913S | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.17); PolyPhen benign (0.046); catalogued as COSV100752771; called by muse, varscan2
- MARCHF11 | c.1055G>A p.R352Q | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.49); catalogued as rs149078493, COSV60126833; called by muse, mutect2, varscan2
- MED13 | c.6331G>C p.E2111Q | Missense Mutation (SNP) | VAF 35/80 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101181018, COSV67261863; called by muse, mutect2, varscan2
- METTL27 | c.250G>A p.E84K | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.854); catalogued as rs782005704, COSV99936434; called by muse, mutect2, varscan2
- MIER3 | c.1052C>T p.T351M (on ENST00000381199 / NM_001297599.2; = p.T350M on NM_152622.4) | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs760775999, COSV67082432; called by muse, mutect2, varscan2
- MSX1 | c.485del p.P162Qfs*55 | Frame Shift Del (DEL) | VAF 14/52 reads (27%) | catalogued as rs762477502; called by pindel, varscan2
- MYO5A | c.1625G>A p.R542H | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs769248373, COSV100697613; called by muse, mutect2, varscan2
- OR10K1 | c.160G>T p.A54S | Missense Mutation (SNP) | VAF 34/132 reads (26%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.81); catalogued as COSV99193496; called by muse, mutect2, varscan2
- PCDHB12 | c.1564G>A p.E522K | Missense Mutation (SNP) | VAF 61/193 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV53397320; called by muse, mutect2, varscan2
- PCDHB6 | c.1843G>A p.V615M | Missense Mutation (SNP) | VAF 50/134 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs782014026, COSV99170103; called by muse, mutect2, varscan2
- PLXNB1 | c.3664C>T p.R1222C | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs749315971, COSV99602788; called by mutect2, varscan2
- PRRC2C | c.7889G>A p.R2630H (on ENST00000367742; = p.R2628H on NM_015172.4) | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs376772339, COSV58916604; called by muse, mutect2, varscan2
- PTPRE | c.787G>A p.V263M | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.443); catalogued as rs141160831; called by muse, mutect2, varscan2
- PYGO1 | c.1109T>C p.I370T | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.192); catalogued as COSV100114611; called by muse, mutect2, varscan2
- RNF167 | c.769G>A p.V257M | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773128293, COSV99337352; called by muse, mutect2, varscan2
- SI | c.3551C>A p.T1184N | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1358763237, COSV100015356; called by muse, mutect2, varscan2
- SLC35A2 | c.82G>A p.A28T | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV55944862; called by mutect2, varscan2
- SLC39A12 | c.782C>A p.T261N | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV101070048; called by muse, mutect2, varscan2
- SLC7A7 | c.446C>T p.P149L | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.67); catalogued as rs796145994; called by muse, mutect2
- SLIT1 | c.641C>G p.S214C | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV99821289; called by muse, mutect2
- SPOCD1 | c.1868G>A p.R623H | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as rs201291524, COSV99929811; called by muse, varscan2
- SYNE2 | c.16765C>T p.L5589F | Missense Mutation (SNP) | VAF 47/139 reads (34%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.924); catalogued as COSV100647515; called by muse, mutect2, varscan2
- THSD7B | c.1756C>A p.P586T | Missense Mutation (SNP) | VAF 27/102 reads (26%) | SIFT tolerated (0.44); PolyPhen benign (0.341); catalogued as COSV99749856; called by muse, mutect2, varscan2
- TMEM214 | c.1384G>A p.V462I | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs756912014, COSV53191756; called by muse, mutect2, varscan2
- TMEM51 | c.505G>A p.E169K | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.131); catalogued as rs545905236, COSV65690317, COSV65690323; called by muse, mutect2, varscan2
- TTN | c.99034C>T p.R33012C (on ENST00000591111; = p.R25588C on NM_003319.4) | Missense Mutation (SNP) | VAF 29/96 reads (30%) | PolyPhen probably damaging (0.942); catalogued as rs773002407, COSV60081695; called by muse, mutect2, varscan2
- UROC1 | c.65G>A p.R22H | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.902); catalogued as rs761537039, COSV99331377; called by muse, mutect2, varscan2
- WDR59 | c.2176C>T p.R726W | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as rs201123075, COSV100049278; called by muse, mutect2, varscan2
- XDH | c.3194G>A p.S1065N | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.745); catalogued as COSV65152034; called by muse, mutect2, varscan2
- YBX3 | c.796G>A p.E266K | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs976660132, COSV99685134; called by muse, mutect2, varscan2
- ZNF197 | c.241A>T p.I81F | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100482072; called by muse, mutect2, varscan2
- ZSCAN20 | c.1591C>T p.R531W | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs953583997, COSV99056000; called by muse, mutect2, varscan2
- ZSCAN29 | c.1688G>A p.R563H | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs755923103, COSV67823242; called by muse, mutect2, varscan2
- AMIGO3 | c.1202_1205dup p.F403Pfs*73 | Frame Shift Ins (INS) | VAF 6/35 reads (17%) | called by pindel, varscan2
- ARID1A | c.4370del p.F1457Sfs*24 | Frame Shift Del (DEL) | VAF 17/49 reads (35%) | called by mutect2, pindel, varscan2
- ATF7IP | c.2903_2913del p.D968Gfs*2 | Frame Shift Del (DEL) | VAF 13/44 reads (30%) | called by mutect2, pindel, varscan2
- CDC25C | c.270del p.A91Qfs*19 | Frame Shift Del (DEL) | VAF 23/85 reads (27%) | called by mutect2, pindel, varscan2
- CSNK2A2 | c.512dup p.L172Afs*40 | Frame Shift Ins (INS) | VAF 17/155 reads (11%) | called by mutect2, pindel, varscan2
- DDHD1 | c.822_857del p.I274_L286delinsM (on ENST00000323669; = p.I471_L483delinsM on NM_030637.3) | In Frame Del (DEL) | VAF 17/49 reads (35%) | called by mutect2, pindel, varscan2
- ETV6 | c.536_538del p.L179_H180delinsY | In Frame Del (DEL) | VAF 23/67 reads (34%) | called by mutect2, pindel, varscan2
- MBD1 | c.761_770dup p.C257* | Nonsense Mutation (INS) | VAF 10/34 reads (29%) | called by mutect2, varscan2
- NCOA4 | c.1456T>C p.F486L | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (0.78); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PSMB4 | c.432_445del p.R145Pfs*13 | Frame Shift Del (DEL) | VAF 6/49 reads (12%) | called by mutect2, pindel, varscan2
- TTN | c.20874dup p.C6959Mfs*2 (on ENST00000591111; = p.C6032Mfs*2 on NM_133378.4 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 17/46 reads (37%) | called by mutect2, varscan2
- ATCAY | c.771C>T p.I257= | Silent (SNP) | VAF 19/50 reads (38%) | catalogued as rs749977698, COSV100008692; called by muse, mutect2, varscan2
- C11orf87 | c.456G>A p.S152= | Silent (SNP) | VAF 14/46 reads (30%) | catalogued as rs754401589, COSV100535773; called by muse, mutect2, varscan2
- CEP350 | c.7542A>T p.R2514= | Silent (SNP) | VAF 16/52 reads (31%) | catalogued as rs754399543, COSV100854602; called by muse, mutect2, varscan2
- CYP1B1 | c.861C>T p.A287= | Silent (SNP) | VAF 14/46 reads (30%) | catalogued as COSV99572676; called by muse, mutect2, varscan2
- DHDH | c.321C>T p.R107= | Silent (SNP) | VAF 33/86 reads (38%) | catalogued as rs762593988, COSV99668301; called by muse, mutect2, varscan2
- DYNC1H1 | c.11994C>T p.P3998= | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as rs1171187875, COSV100794819; called by muse, mutect2, varscan2
- FBXO31 | c.831C>G p.T277= | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as COSV100291402, COSV61151569; called by muse, mutect2, varscan2
- GPR18 | c.657G>A p.T219= | Silent (SNP) | VAF 18/43 reads (42%) | catalogued as rs754746735, COSV100540560; called by muse, mutect2, varscan2
- INHBE | c.33G>T p.V11= | Silent (SNP) | VAF 9/32 reads (28%) | catalogued as COSV99875274; called by muse, mutect2, varscan2
- MMP12 | c.591C>T p.F197= | Silent (SNP) | VAF 12/35 reads (34%) | catalogued as rs202054339; called by muse, varscan2
- NHSL2 | c.366C>T p.P122= (on ENST00000510661; = p.P488= on NM_001013627.2) | Silent (SNP) | VAF 7/15 reads (47%) | catalogued as rs1176862811, COSV101030039; called by muse, mutect2, varscan2
- NPTX2 | c.777C>T p.S259= | Silent (SNP) | VAF 15/44 reads (34%) | catalogued as rs764342757, COSV55717675; called by muse, mutect2, varscan2
- SPOCD1 | c.234C>T p.V78= | Silent (SNP) | VAF 11/44 reads (25%) | catalogued as COSV99929812; called by muse, mutect2, varscan2
- UNC13D | c.2211G>T p.L737= | Silent (SNP) | VAF 10/29 reads (34%) | catalogued as COSV99256619; called by muse, mutect2, varscan2
- NDE1 | c.1030+2929G>A | Intron (SNP) | VAF 46/135 reads (34%) | catalogued as rs772365768, COSV100258826; called by muse, mutect2, varscan2
